Surgical pathology report (de-identified scan), TCGA case TCGA-WC-A88A, project TCGA-UVM (Uveal Melanoma), tissue source site MD Anderson, specimen TCGA-WC-A88A-01A (Primary Tumor).

[page 1 of 2]
Accession:

Specimen Date/Time:

DIAGNOSIS

(A) RIGHT CHOROIDAL BIOPSY:

Sample for send out testing only, See comment.

(B) RIGHT GLOBE:

(>90 %)

1-30%

IRIDOCILIOCHOROIDAL MELANOMA, MIXED SPINDLED AND EPITHELIOID CELL TYPES, see comment

Invades ciliary body and iris extending into the anterior chamber.

Scleral invasion: Present with probable involvement of the canal of schlemm

Extraocular extension: Present, 1 mm focus.

Optic nerve and optic nerve margin, negative for tumor

Vortex veins, negative for tumor

COMMENT

The specimen for part A was sent to

for further diagnostic testing ordered by

, which will t

reported separately within the scan documents of

The tumor in part B has a 19 mm base and 12 mm height. The mitotic rate is 2 per 10 hpf. There are areas of Spindle type and epithelial cells. The site of origin of ciliary body versus choroid cannot be definitively determined. The extraocular extension in the region just outside of the limbus and may represent invasion via the canal of Schlemm versus direct invasion of the sclera in this region. Levels were examined without definitive determination of the pathway of extraocular extension.

PATHOLOGIC STAGE BASED ON PATHOLOGY MATERIAL REVIEWED IN THIS ACCESSION

Primary tumor: pT4d

Regional lymph nodes: pNx

Distant metastases: pMx

ICD-O-3

Melanoma, epithelioid &
spindle cell mixed 8770/3
Site: Choroid C693
7/11/14

(American Joint Committee on Cancer, 7th Edition, 2010)

GROSS DESCRIPTION

(A) RIGHT CHOROIDAL BIOPSY, NOT FOR PERMANENT AND SHIPPED OUT VIA _____ - Received on a clear, plastic tube what grossly appears as a clear liquid content (approximately 2 ml). Specimen will be shipped out.

(B) RIGHT GLOBE - An intact globe (24 x 23 x 23 mm) with an attached 7 mm optic nerve. The scleral region adjacent to limbus at approximately the 7 o'clock position shows a hyperpigmented lesion beneath the conjunctiva approximately 1 mm mm with a height less than 1 mm. The cornea is clear formed by a 12 x 11 mm cornea and a round 5 mm pupil surrounded brown iris. By transillumination, the globe shows a mass beginning at the region of the limbus extending to approximately the nerve, from approximately 6 to 8 o'clock. Tissue is harvested fresh and the eye is opened showing a choroidal base mass involving the ciliary body and iris with possible basal dimension of 25 mm however as the tumor may be pedunculated a portion of this size may without direct choroidal involvement to be evaluated microscopically. The maximum height is 12 mm with the closest to the iris having a separate nodular peak of only 3 mm. The tumor does not involve the optic nerve grossly grossly approximately 12 mm from the optic nerve to the tumor adherent to the sclera.

INK CODE: Yellow - area of sclera with extraocular extension.

SECTION CODE: B1, vortex vein; B2, optic nerve margin and detached retina; B3, tumor and cornea; B4, calotte with extraocular extension yellow area; B5, pupil - optic nerve section; B6, additional sections of iris and sclera.

BIOMARKER TESTING

[page 2 of 2]
Accession:

Specimen Date/Time:

Primary Tumor Block: B5, Normal Block: B2

CLINICAL HISTORY

Uveal melanoma.

SNOMED CODES

T-AA000 M-97203 "Some tests reported here may have been developed and performance characteristics determined by tests have not been specifically cleared or approved by the U.S. Food and Drug Administration."

Entire report and diagnosis completed by:

-----END OF REPORT-----

Diagnosis Discernible		✓
Primary Tumor Site Discernible		✓
tPNA Discernible		✓
Major Histological History		✓
Qual/Symptom/Sign/Prod		✓
Case is (Initial)		

10/25/13

10-7-13

Source: NCI Genomic Data Commons file 98df5d7f-d998-4816-bd0e-9a1c35d90c5e (TCGA-WC-A88A.8A79DCBE-B2F9-48B3-AA7C-1F16608CF1C7.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).